Gene-level copy-number profile of tumor specimen TCGA-VQ-A8DV-01A from TCGA case TCGA-VQ-A8DV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.3 years (17,630 days).
Specimen TCGA-VQ-A8DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6afcac68-0020-4ebe-9d68-6ca8985c24be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8DV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e30334f2-c8e5-4ea6-bb7a-906e94bda83a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 2: 6,647; copy number 3: 17,058; copy number 4: 17,534; copy number 5: 6,761; copy number 6: 6,862; copy number 7: 1,864; copy number 8: 2,039; copy number 9: 604; copy number 10: 421; copy number 11: 12; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8DV-01A-12D-A363-01): tumor purity 0.58, ploidy 4.09, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:14,692,129–14,777,727, 2 genes: TBCAP2, AL031293.1.
- chr5:120,464,300–121,060,953, 6 genes: PRR16, PRELID3BP8, RNU4-69P, AC114284.1, AC008565.1, AC113352.1.
- chr9:132,878,027–132,890,201, 1 gene: SPACA9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,039 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,528,364–1,607,354, 2 genes, copy number 15: AL512329.2, FOXCUT.
- chr12:53,064,316–53,506,431, 31 genes, copy number 10 (within-gene range 6–10): SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, AC021072.1, MFSD5, ESPL1, PFDN5, AC073611.1, MYG1-AS1, MYG1, AAAS, SP7, SP1, AMHR2, PRR13, AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2.
- chr12:53,506,690–53,507,638, 1 gene, copy number 10: NPFF.
- chr12:53,513,891–53,517,608, 1 gene, copy number 10: AC023509.2.
- chr12:57,591,174–60,269,686, 59 genes, copy number 9 (within-gene range 4–9): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1.
- chr13:87,890,172–94,408,020, 58 genes, copy number 9–10 (within-gene range 7–10): TET1P1, LINC00373, RPL29P29, AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29.
- chr13:94,025,470–94,596,242, 4 genes, copy number 9 (within-gene range 7–9): RNA5SP35, GPC6-AS1, DCT, TGDS.
- chr19:32,243,965–39,111,493, 317 genes, copy number 9–11 (broad region; genes not listed).
- chr19:39,134,882–39,136,463, 1 gene, copy number 11: AC011443.1.
- chr20:43,063,326–64,313,132, 565 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
